Somatic mutation profile of tumor specimen TCGA-DU-6408-01A (aliquot TCGA-DU-6408-01A-11D-1705-08) from TCGA case TCGA-DU-6408, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 24.0 years (8,752 days).
Specimen TCGA-DU-6408-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dbc2c81-354e-4abf-91c8-13455c584d9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6408-10A (Blood Derived Normal), aliquot TCGA-DU-6408-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/916706de-14e8-49e8-b9fd-5520d4883513

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Frame Shift Del 2, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.763A>T p.I255F | Missense Mutation (SNP) | VAF 17/38 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1057519995, COSV52663197, COSV52713501, COSV52816344; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.5351T>G p.I1784S | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64875034; called by muse, varscan2
- ATRX | c.5289T>G p.N1763K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64879185; called by muse, varscan2
- IGF2BP1 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.436); catalogued as COSV51733160; called by muse, mutect2, varscan2
- KL | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs373063965; called by muse, mutect2, varscan2
- NDNF | c.1226T>A p.L409H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV65634034; called by muse, mutect2, varscan2
- PLCG2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63871962, COSV63873535; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1550A>G p.D517G | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV50252230; called by muse, mutect2, varscan2
- RAC2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs1415916204, COSV50773868; called by muse, mutect2, varscan2
- SIM1 | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV53493912; called by muse, mutect2
- SLC26A7 | c.1878G>C p.E626D | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as COSV52586835, COSV52597367; called by muse, mutect2
- SYCP1 | c.456+1G>A p.X152_splice | Splice Site (SNP) | VAF 38/144 reads (26%) | catalogued as COSV65699025; called by muse, mutect2, varscan2
- NES | c.4717_4720del p.G1573Tfs*14 | Frame Shift Del (DEL) | VAF 26/68 reads (38%) | called by mutect2, pindel, varscan2
- OR8G2P | c.480del p.G161Afs*4 | Frame Shift Del (DEL) | VAF 38/329 reads (12%) | called by mutect2, pindel, varscan2
- PCDHGA5 | c.2121C>T p.F707= | Silent (SNP) | VAF 64/124 reads (52%) | catalogued as rs372498112, COSV53952815; called by muse, mutect2, varscan2
- SPECC1 | c.2223G>A p.E741= | Silent (SNP) | VAF 51/112 reads (46%) | catalogued as rs752687290, COSV54961321; called by muse, mutect2, varscan2
